Somatic mutation profile of tumor specimen 0DHQFF from CCDI case PBBUYK, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Occipital lobe; Age at diagnosis: 12.2 years (4,452 days).
Specimen 0DHQFF: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) be4438c3-3877-49aa-a631-c6e7ef9cf225.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DHQDJ (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/678cbe4e-7709-4772-b4c9-11d6af0fc104

The open-access MAF lists 20 somatic variants for this specimen: 14 protein-altering or splice-affecting, 4 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Silent 4, Nonsense Mutation 2, Intron 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 176/470 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- ABCA5 | c.2102A>G p.K701R | Missense Mutation (SNP) | VAF 152/406 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs373286543; called by muse, mutect2
- ARID1A | c.2365C>T p.Q789* | Nonsense Mutation (SNP) | VAF 20/439 reads (5%) | catalogued as COSV99055332; called by muse, mutect2
- COL17A1 | c.4082G>A p.G1361E | Missense Mutation (SNP) | VAF 16/461 reads (3%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.003); catalogued as rs1389099390; called by muse, mutect2
- HOXB4 | c.722C>T p.P241L | Missense Mutation (SNP) | VAF 27/644 reads (4%) | SIFT tolerated (0.36); PolyPhen benign (0.04); catalogued as rs760942924, COSV60178238; called by muse, mutect2
- TENM3 | c.4282C>T p.R1428W | Missense Mutation (SNP) | VAF 165/426 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as rs371891390; called by muse, mutect2, varscan2
- TUBB6 | c.284C>T p.T95M | Missense Mutation (SNP) | VAF 26/844 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.891); catalogued as COSV52313891; called by muse, mutect2
- ZNF574 | c.857G>A p.R286Q | Missense Mutation (SNP) | VAF 114/282 reads (40%) | SIFT tolerated (0.59); PolyPhen benign (0.439); catalogued as rs1178580185; called by muse, mutect2, varscan2
- ANXA5 | c.780G>A p.K260= | Splice Region (SNP) | VAF 132/372 reads (35%) | called by muse, mutect2, varscan2
- ITIH4 | c.889C>G p.L297V | Missense Mutation (SNP) | VAF 291/709 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- PIEZO2 | c.5973G>T p.K1991N | Missense Mutation (SNP) | VAF 48/901 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.062); called by muse, mutect2
- RAG1 | c.1903G>T p.A635S | Missense Mutation (SNP) | VAF 206/603 reads (34%) | SIFT tolerated, low confidence (0.68); PolyPhen benign (0.119); called by muse, mutect2, varscan2
- SRSF7 | c.142G>A p.G48R | Missense Mutation (SNP) | VAF 232/714 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- USP9X | c.4864C>T p.Q1622* | Nonsense Mutation (SNP) | VAF 143/192 reads (74%) | called by muse, mutect2, varscan2
- ACOX2 | c.1566G>T p.T522= | Silent (SNP) | VAF 74/838 reads (9%) | called by muse, mutect2
- CYYR1 | c.153C>T p.Y51= | Silent (SNP) | VAF 227/560 reads (41%) | catalogued as rs764106284; called by muse, mutect2, varscan2
- OBSCN | c.9513C>T p.G3171= | Silent (SNP) | VAF 190/585 reads (32%) | catalogued as rs752200908, COSV52751331; called by muse, mutect2, varscan2
- OR4N2 | c.252C>T p.D84= | Silent (SNP) | VAF 48/1532 reads (3%) | called by muse, mutect2
- CYP2E1 | c.488-85C>T | Intron (SNP) | VAF 67/139 reads (48%) | called by muse, mutect2
- HMG20B | c.941+75G>A | Intron (SNP) | VAF 41/101 reads (41%) | called by muse, mutect2, varscan2
